Somatic mutation profile of tumor specimen BA2399D (aliquot aq-BA2399D) from BEATAML1.0 case 2196, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.9 years (20,433 days).
Specimen BA2399D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b223a604-1edf-49dc-ac85-43c01be1ecca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2364D (Solid Tissue Normal), aliquot aq-BA2364D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39daee78-cbc0-447c-9280-418706da9422

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 74/144 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PPIL2 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs575962422; called by muse, varscan2
- ST13 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV99344487; called by muse, mutect2, varscan2
- PAX8 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- RBFOX1 | c.840C>A p.Y280* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | called by muse, varscan2
- REV3L | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF467 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- SERINC2 | c.180C>A p.G60= (on ENST00000373709 / NM_178865.5; = p.G64= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs146127705; called by muse, mutect2
- TERT | c.1573+46G>A | Intron (SNP) | VAF 19/40 reads (48%) | called by mutect2, varscan2
